Gene-level copy-number profile of tumor specimen TARGET-10-PATEMI-09A from TARGET case TARGET-10-PATEMI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.8 years (6,491 days).
Specimen TARGET-10-PATEMI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.cf99f78c-649a-5494-a534-ee67a839f17c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATEMI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 388 have no estimate.
https://portal.gdc.cancer.gov/files/00deaaa2-d58e-4bee-8597-7ba34de77eed

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 541; copy number 1: 64; copy number 2: 59,276; copy number 3: 269; copy number 4: 85.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:99,996,547–100,067,954, 13 genes: EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7.
- chr9:61,581,813–61,662,690, 4 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr11:55,602,360–55,652,854, 3 genes: OR4C11, OR4P4, OR4S2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 64. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
